Gene-level copy-number profile of tumor specimen TCGA-DD-AADO-01A from TCGA case TCGA-DD-AADO, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 55.1 years (20,139 days).
Specimen TCGA-DD-AADO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.f424e5ee-4b5c-4185-8c6a-728544889651.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AADO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bef3fbf7-28b3-4715-a696-ddd6a1a53fae

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 507; copy number 2: 10,780; copy number 3: 16,590; copy number 4: 17,145; copy number 5: 7,712; copy number 6: 4,688; copy number 7: 351; copy number 8: 1,775; copy number 9: 198; copy number 10: 67.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AADO-01A-11D-A40Q-01): tumor purity 0.62, ploidy 3.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 265 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:39,249,266–43,596,046, 52 genes, copy number 10 (within-gene range 5–10): MAP4K3, AC007684.1, AC007684.2, MAP4K3-DT, TMEM178A, THUMPD2, SLC8A1-AS1, AC007253.1, SLC8A1, AC007877.1, AC007317.1, AC007317.2, LINC01794, HNRNPA1P57, AC009413.1, LDHAP3, RPS12P4, Y_RNA, LINC01913, RNU4-63P, LINC01914, C2orf91, AC013480.1, PKDCC, EML4-AS1, EML4, COX7A2L, AC025750.2, KCNG3, VDAC1P13, RPS13P3, MTA3, Metazoa_SRP, AC025750.1, AC074375.1, RNU6-137P, OXER1, HAAO, FTOP1, CHORDC1P1, AC016735.1, LINC01819, LINC02590, RNU6-242P, LINC02580, AC010883.2, AC010883.3, ZFP36L2, LINC01126, AC010883.1, THADA, RNU6-958P.
- chr2:147,472,133–147,495,540, 2 genes, copy number 9: Y_RNA, RNU6-715P.
- chr2:154,590,407–167,941,180, 159 genes, copy number 9 (broad region; genes not listed).
- chr7:40,135,005–40,860,763, 1 gene, copy number 9 (within-gene range 8–9): SUGCT.
- chr7:40,538,127–41,705,834, 5 genes, copy number 9: SUGCT-AS1, AC005160.1, LINC01450, LINC01449, INHBA.
- chr7:51,382,284–54,455,093, 31 genes, copy number 9: CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC006478.1, AC006478.2, AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3.
- chr8:135,859,369–139,127,953, 15 genes, copy number 10: LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2.

Autosomal genes at a single copy (total copy number 1): 31. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
